Somatic mutation profile of tumor specimen MP2PRT-PARYAJ-TMP1-A (aliquot MP2PRT-PARYAJ-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARYAJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (425 days).
Specimen MP2PRT-PARYAJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65ab858a-3fd0-4327-9e8e-cf0f1cd32e20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARYAJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARYAJ-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/529e0467-48c2-4f14-82b1-0d33c7b205e8

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 105/292 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LRRC74B | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 20/437 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs905372138; called by muse, mutect2
- ARHGAP45 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 136/401 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEC3 | c.1728+7G>T | Splice Region (SNP) | VAF 235/302 reads (78%) | called by muse, varscan2
- MYOZ1 | c.345C>A p.G115= | Silent (SNP) | VAF 166/489 reads (34%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899616 ins GG | 3'Flank (INS) | VAF 165/453 reads (36%) | called by mutect2, pindel, varscan2
